Somatic mutation profile of tumor specimen TARGET-10-PARIAD-04A (aliquot TARGET-10-PARIAD-04A-01D) from TARGET case TARGET-10-PARIAD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (596 days).
Specimen TARGET-10-PARIAD-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80549684-8160-4f07-8bed-8a5da79827a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIAD-10A (Blood Derived Normal), aliquot TARGET-10-PARIAD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff07c9c5-2350-42fc-9ca8-9860d7a6b9fa

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 2, Silent 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12B | c.1057G>A p.V353M (on ENST00000337334 / NM_001206673.2; = p.V276M on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs142210572, COSV53585701; called by muse, mutect2, varscan2
- COL4A4 | c.4014T>A p.F1338L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61634281; called by muse, mutect2
- CPQ | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 197/414 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs373415893, COSV99613015; called by muse, mutect2, varscan2
- DGKB | c.516+2T>C p.X172_splice | Splice Site (SNP) | VAF 18/289 reads (6%) | catalogued as rs767622044; called by muse, mutect2
- KCNH6 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs781598801, COSV59004879; called by muse, mutect2, varscan2
- KRT25 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 134/278 reads (48%) | catalogued as rs758921574, COSV56445775; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 143/306 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE7B | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs536911085, COSV100367870, COSV57502650; called by muse, mutect2, varscan2
- RYR2 | c.8414G>A p.R2805H | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1247067433, COSV63695835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOAT2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs141175448; called by muse, mutect2, varscan2
- UBE2H | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs1484890786, COSV100842468, COSV62921185; called by muse, mutect2, varscan2
- WNT10B | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 50/111 reads (45%) | catalogued as rs775699954, COSV56405646; called by muse, mutect2, varscan2
- EVPL | c.574T>A p.Y192N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FCGBP | c.11014G>A p.D3672N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OCRL | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.385); called by muse, varscan2
- PCDHA9 | c.1242C>A p.D414E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PDE1A | c.79dup p.M27Nfs*20 | Frame Shift Ins (INS) | VAF 35/348 reads (10%) | called by mutect2, pindel
- PUSL1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.038); called by muse, varscan2
- RFPL1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.22); called by muse, mutect2
- ENPP3 | c.1590A>G p.A530= | Silent (SNP) | VAF 153/370 reads (41%) | called by muse, mutect2, varscan2
- POFUT2 | c.660C>G p.A220= | Silent (SNP) | VAF 134/297 reads (45%) | catalogued as COSV57960079; called by muse, mutect2, varscan2
- DST | c.4297-1929G>A | Intron (SNP) | VAF 109/243 reads (45%) | catalogued as rs200347043, COSV55004610; called by muse, mutect2, varscan2
- IL5RA | c.994+2014C>T | Intron (SNP) | VAF 308/691 reads (45%) | catalogued as rs140525458, COSV56521860, COSV99842712; called by muse, mutect2, varscan2
